Gene-level copy-number profile of tumor specimen TCGA-XE-AANQ-01A from TCGA case TCGA-XE-AANQ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choriocarcinoma combined with other germ cell elements; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 19.3 years (7,044 days).
Specimen TCGA-XE-AANQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 28b29703-4f1e-4af9-9fc9-85326191a5e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/9cace6f1-a953-4afc-8141-8ea1b1ccad5f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 477; copy number 2: 21,022; copy number 3: 32,905; copy number 4: 2,250; copy number 5: 936; copy number 6: 454; copy number 7: 8; copy number 8: 2; copy number 9: 82; copy number 10: 747.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 839 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:88,032,011–88,887,573, 4 genes, copy number 7 (within-gene range 6–7): MMP16, AC090578.1, RNA5SP272, AC090568.1.
- chr12:66,767–34,249,958, 831 genes, copy number 8–10 (broad region; genes not listed).
- chr21:8,603,547–8,761,335, 4 genes, copy number 7: RPSAP68, CR381572.2, CR381572.1, LINC01666.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
